Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7472, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7472-01A (Primary Tumor).

Path Report

Addendum Discussion:

The calculated MIB-1 Labeling Index overall appears low with focal regions increased at 4.9%. Overall, the histologic features of this tumor are consistent with a low grade oligodendroglioma; however, the MIB-1 Labeling index is borderline for a low grade oligodendroglioma (<5%; WHO,). Close followup for recurrence and/or anaplastic progression may be warranted.

Brain Tumor, Biopsy and Resection:

Oligodendroglioma (WHO grade II)
MIB-1 Labeling Index = 4.9%

Microscopic Description:

1,2 Sections of gray and white matter demonstrate a diffusely infiltrating glioma. The tumor is mildly to moderately hypercellular. It is composed of cells with round to somewhat irregular nuclei and scant processes. Most have perinuclear halos. Only a rare mitotic figure is seen. No microvascular proliferation or necrosis is present.

Source: NCI Genomic Data Commons file 500136f6-e2ee-40f0-8893-10ad76cca3f3 (TCGA-HT-7472.5842F023-208B-48DD-9C9D-6644A928F4C2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).